Gene-level copy-number profile of tumor specimen TCGA-CN-5370-01A from TCGA case TCGA-CN-5370, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 78.2 years (28,549 days).
Specimen TCGA-CN-5370-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.9a0d333d-f5cf-4123-9277-0c4452080fd9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-5370-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b098305e-a46b-4ad1-8afb-d1544b188004

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,740; copy number 2: 48,004; copy number 3: 2,394; copy number 4: 220; copy number 5: 317; copy number 8: 87; copy number 9: 29; copy number 13: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-5370-01A-01D-2010-01): tumor purity 0.44, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 461 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:69,471,452–74,005,609, 67 genes, copy number 5–13 (broad region; genes not listed).
- chr5:50,396,192–52,080,987, 25 genes, copy number 5: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118.
- chr8:46,028,804–51,015,165, 77 genes, copy number 5 (broad region; genes not listed).
- chr9:14,475–7,961,224, 139 genes, copy number 5 (broad region; genes not listed).
- chr9:34,689,570–36,487,548, 87 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr14:22,086,407–22,509,406, 66 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,359. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
